Gene-level copy-number profile of tumor specimen AP-RQNH-A5 from APOLLO case AP-RQNH, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2.
Specimen AP-RQNH-A5: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2a865b1a-eb3b-4ec6-b241-ba4556a2bb29.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-RQNH-LE (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,219 have no estimate.
https://portal.gdc.cancer.gov/files/4e80c91f-d4dd-4e6c-8c8b-fd576cac08e4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 2: 50,936; copy number 3: 7,451; copy number 4: 17.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
